Gene-level copy-number profile of tumor specimen C3L-00093-01 from CPTAC case C3L-00093, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 66.5 years (24,301 days).
Specimen C3L-00093-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ea612320-a86a-4f56-87dc-f7a38449a046.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-00093-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/a9196d53-1e40-4f61-baa6-8fedb82bec46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 5,505; copy number 2: 44,096; copy number 3: 8,076; copy number 4: 166; copy number 5: 108; copy number 6: 66; copy number 7: 119; copy number 8: 210; copy number 9: 1; copy number 10: 6; copy number 11: 2; copy number 12: 4; copy number 15: 29; copy number 18: 4; copy number 21: 12.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:61,211,652–61,212,203, 1 gene (within-gene range 0–2): RPL17P19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 561 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–693,352, 27 genes, copy number 5: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:979,365–1,594,620, 21 genes, copy number 8–18: AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3.
- chr5:6,839,460–7,219,291, 1 gene, copy number 7 (within-gene range 4–7): LINC02196.
- chr5:7,047,227–7,069,351, 2 genes, copy number 7: RNA5SP176, AC025756.1.
- chr9:20,331,446–21,077,942, 13 genes, copy number 5–7: AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1.
- chr9:22,446,824–22,455,740, 1 gene, copy number 7: DMRTA1.
- chr19:27,638,483–38,229,714, 345 genes, copy number 5–8 (broad region; genes not listed).
- chr19:38,374,536–41,062,444, 151 genes, copy number 7–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,505. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
